Somatic mutation profile of tumor specimen MMRF_2291_1_BM_CD138pos (aliquot MMRF_2291_1_BM_CD138pos_T1_KHS5U_L09520) from MMRF case MMRF_2291, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 75.5 years (27,576 days).
Specimen MMRF_2291_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b6825731-7f03-40da-a86b-2b1f52afed4e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2291_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2291_1_PB_Whole_C3_KHS5U_L09521; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f0eb5bbc-2007-4233-a497-38f82bb3a64d

The open-access MAF lists 148 somatic variants for this specimen: 57 protein-altering or splice-affecting, 24 silent, 67 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, 3'UTR 41, Silent 24, Intron 20, 5'UTR 5, Nonsense Mutation 5, Frame Shift Del 2, In Frame Del 1, Translation Start Site 1, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ADAM2 | c.10G>A p.V4I | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs769082387, COSV55864232; called by muse, mutect2, varscan2
- ADAMTS12 | c.2533C>T p.R845C | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs377712954, COSV61260425; called by muse, mutect2
- AMELY | c.332G>A p.R111H (on ENST00000383036 / NM_001364814.1; = p.R97H on NM_001143.1) | Missense Mutation (SNP) | VAF 60/70 reads (86%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.938); catalogued as rs1569360849; called by muse, mutect2, varscan2
- DUSP8 | c.750C>G p.I250M | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59030157; called by muse, mutect2, varscan2
- ECM1 | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs138083168; called by muse, mutect2, varscan2
- FSIP2 | c.14461G>A p.D4821N | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs943701755; called by muse, mutect2, varscan2
- IGHV2-70 | c.268A>T p.I90F | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as rs372477786; called by muse, varscan2
- IGHV2-70 | c.95A>G p.K32R | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs371469802; called by muse, varscan2
- IGLV3-1 | c.130G>C p.D44H | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as rs371113616; called by muse, varscan2
- IGLV3-1 | c.145A>C p.K49Q | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.055); catalogued as rs192957059; called by muse, varscan2
- KLHL9 | c.794C>A p.T265N | Missense Mutation (SNP) | VAF 138/174 reads (79%) | SIFT tolerated (0.49); PolyPhen benign (0.129); catalogued as COSV100756994; called by muse, mutect2, varscan2
- KLK10 | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.186); catalogued as COSV100010902; called by mutect2, varscan2
- KLK8 | c.686G>T p.G229V | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51591792, COSV99143854, COSV99144044; called by muse, mutect2, varscan2
- MCHR1 | c.914C>T p.T305M | Missense Mutation (SNP) | VAF 49/82 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.036); catalogued as rs550313335, CM106863, COSV50760512; called by muse, mutect2, varscan2
- MCM3AP | c.1381A>G p.K461E | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as rs374894216, COSV99386813; called by muse, mutect2, varscan2
- NEUROG2 | c.517C>A p.H173N | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as COSV57638229; called by muse, mutect2, varscan2
- NKX6-1 | c.237del p.L80Sfs*23 | Frame Shift Del (DEL) | VAF 24/76 reads (32%) | catalogued as rs745904099; called by mutect2, pindel, varscan2
- NLRP10 | c.1007G>A p.R336H | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs776023158, COSV60780109; called by muse, mutect2, varscan2
- PCSK2 | c.1879G>A p.V627M | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as rs757047936; called by muse, mutect2, varscan2
- PFDN2 | c.19C>T p.R7C | Missense Mutation (SNP) | VAF 51/114 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); catalogued as rs565609283, COSV63502644; called by muse, mutect2, varscan2
- PITPNM1 | c.146C>T p.T49M | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.298); catalogued as rs1178283472, COSV56873440; called by muse, mutect2, varscan2
- PPP1R26 | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.683); catalogued as rs147273345; called by muse, mutect2, varscan2
- SI | c.3127G>A p.E1043K | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52275009; called by muse, mutect2, varscan2
- SLC18A2 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 56/134 reads (42%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs763736721, COSV53690955; called by muse, mutect2, varscan2
- SLC6A2 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 103/273 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as rs1353298980, COSV54914945; called by muse, mutect2, varscan2
- TMEM25 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 83/139 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs113919895, COSV57096193; called by muse, mutect2, varscan2
- TNFRSF11B | c.286G>T p.E96* | Nonsense Mutation (SNP) | VAF 41/123 reads (33%) | catalogued as COSV99816362; called by muse, mutect2, varscan2
- WNT3A | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs749224268, COSV99470357; called by mutect2, varscan2
- ANXA1 | c.302C>T p.T101I | Missense Mutation (SNP) | VAF 54/146 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.058); called by muse, mutect2
- ANXA1 | c.682A>T p.R228* | Nonsense Mutation (SNP) | VAF 42/216 reads (19%) | called by muse, mutect2, varscan2
- CALR | c.820G>T p.E274* | Nonsense Mutation (SNP) | VAF 77/181 reads (43%) | called by muse, mutect2, varscan2
- CCDC18 | c.2806_2811del p.L936_T937del (on ENST00000343253 / NM_001306076.1; = p.L937_T938del on NM_206886.4) | In Frame Del (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
- CRIM1 | c.1748A>G p.D583G | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- DAAM2 | c.2510+2T>G p.X837_splice | Splice Site (SNP) | VAF 49/116 reads (42%) | called by muse, mutect2, varscan2
- DAGLA | c.1702C>A p.L568M | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- EAF1 | c.574G>T p.G192W | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- FSHR | c.702del p.S235Afs*4 | Frame Shift Del (DEL) | VAF 4/23 reads (17%) | called by mutect2, pindel
- GPR141 | c.850G>T p.V284F | Missense Mutation (SNP) | VAF 71/186 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- IGHE | c.528C>A p.S176R | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- IGKV4-1 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 24/42 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, varscan2
- KCNG3 | c.831G>T p.E277D | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- LMOD3 | c.1480C>T p.Q494* | Nonsense Mutation (SNP) | VAF 31/87 reads (36%) | called by muse, mutect2, varscan2
- MERTK | c.2972C>G p.S991C | Missense Mutation (SNP) | VAF 95/238 reads (40%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); called by muse, varscan2
- NLRP5 | c.1015G>T p.E339* | Nonsense Mutation (SNP) | VAF 89/444 reads (20%) | called by muse, mutect2, varscan2
- NLRX1 | c.1367G>C p.G456A | Missense Mutation (SNP) | VAF 74/286 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR10J3 | c.211G>C p.E71Q | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- PCDH15 | c.2489A>G p.E830G | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDH9 | c.1745C>T p.S582F | Missense Mutation (SNP) | VAF 66/170 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- S1PR1 | c.1135A>T p.N379Y | Missense Mutation (SNP) | VAF 50/169 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- SOHLH2 | c.785C>G p.A262G | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TENM4 | c.1014C>G p.N338K | Missense Mutation (SNP) | VAF 55/113 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- TNRC6B | c.597G>T p.E199D | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- WWC1 | c.2747G>A p.G916E | Missense Mutation (SNP) | VAF 41/153 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- XK | c.1196G>A p.C399Y | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); called by muse, mutect2
- ZFHX4 | c.236A>T p.E79V | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); called by muse, mutect2
- ZNF646 | c.2419C>A p.H807N | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.076); called by muse, mutect2
- ALDH1A2 | c.84G>A p.S28= | Silent (SNP) | VAF 19/284 reads (7%) | catalogued as rs756005921, COSV99990661; called by muse, mutect2
- B4GALNT4 | c.1785C>A p.A595= | Silent (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2, varscan2
- CFAP46 | c.4962C>T p.N1654= | Silent (SNP) | VAF 18/51 reads (35%) | called by mutect2, varscan2
- CRIM1 | c.1629C>A p.I543= | Silent (SNP) | VAF 27/122 reads (22%) | catalogued as rs1467009101; called by muse, mutect2, varscan2
- DUSP8 | c.1839G>C p.A613= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as rs768081508; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2460C>T p.F820= | Silent (SNP) | VAF 22/195 reads (11%) | catalogued as rs375893153; called by muse, mutect2, varscan2
- ETNPPL | c.1491C>T p.L497= | Silent (SNP) | VAF 10/206 reads (5%) | called by muse, mutect2
- HAO2 | c.102G>A p.T34= | Silent (SNP) | VAF 30/258 reads (12%) | catalogued as rs762037511, COSV58041485; called by muse, mutect2, varscan2
- IGHV2-70 | c.210A>C p.A70= | Silent (SNP) | VAF 49/137 reads (36%) | catalogued as rs61732229; called by muse, varscan2
- IGLL5 | c.87G>A p.L29= | Silent (SNP) | VAF 28/66 reads (42%) | catalogued as rs1370945224; called by muse, varscan2
- JAK1 | c.306C>A p.S102= | Silent (SNP) | VAF 3/50 reads (6%) | called by muse, mutect2
- MERTK | c.2619C>G p.V873= | Silent (SNP) | VAF 40/164 reads (24%) | called by muse, mutect2, varscan2
- PNMA8B | c.1659C>A p.T553= | Silent (SNP) | VAF 18/118 reads (15%) | catalogued as COSV100885316; called by muse, mutect2, varscan2
- POU3F3 | c.954G>A p.T318= | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as rs1467353970, COSV100796845; called by muse, mutect2, varscan2
- PROZ | c.1194C>T p.I398= | Silent (SNP) | VAF 66/219 reads (30%) | called by muse, mutect2, varscan2
- PRR5 | c.570C>T p.S190= (on ENST00000336985 / NM_181333.4; = p.S181= on NM_015366.4) | Silent (SNP) | VAF 34/51 reads (67%) | catalogued as rs1337910959; called by muse, mutect2, varscan2
- RPLP1 | c.63G>A p.V21= | Silent (SNP) | VAF 3/38 reads (8%) | catalogued as rs1431674977; called by muse, mutect2
- TAF1C | c.348C>T p.D116= | Silent (SNP) | VAF 97/257 reads (38%) | catalogued as rs200908474; called by muse, mutect2, varscan2
- TENT5B | c.495G>A p.T165= | Silent (SNP) | VAF 92/275 reads (33%) | catalogued as rs765170340, COSV100006417; called by muse, mutect2, varscan2
- TJP1 | c.4332C>T p.S1444= | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as rs369354122; called by muse, mutect2, varscan2
- TTC23L | c.510G>A p.L170= | Silent (SNP) | VAF 19/72 reads (26%) | called by muse, mutect2, varscan2
- WDR82 | c.111C>T p.I37= | Silent (SNP) | VAF 59/144 reads (41%) | called by muse, mutect2, varscan2
- ZIC1 | c.1041C>T p.S347= | Silent (SNP) | VAF 64/162 reads (40%) | catalogued as COSV51554209, COSV51554742, COSV51558211; called by muse, mutect2, varscan2
- ZNF729 | c.774T>C p.H258= | Silent (SNP) | VAF 68/156 reads (44%) | called by muse, mutect2, varscan2
- AC093802.1 | n.1914+8743C>A | Intron (SNP) | VAF 35/86 reads (41%) | called by muse, mutect2, varscan2
- ADGRL2 | c.3102-617T>C | Intron (SNP) | VAF 23/69 reads (33%) | called by muse, mutect2, varscan2
- ARHGAP30 | c.-193A>T | 5'UTR (SNP) | VAF 10/168 reads (6%) | called by muse, mutect2
- ARHGAP33 | c.1567+11C>G | Intron (SNP) | VAF 33/153 reads (22%) | called by muse, mutect2, varscan2
- ARID5B | c.*1522T>C | 3'UTR (SNP) | VAF 8/57 reads (14%) | called by muse, mutect2, varscan2
- ARID5B | c.*2238T>C | 3'UTR (SNP) | VAF 25/74 reads (34%) | called by muse, mutect2, varscan2
- ASB4 | c.*1484G>A | 3'UTR (SNP) | VAF 11/49 reads (22%) | called by muse, mutect2, varscan2
- B4GALT5 | c.*1918A>T | 3'UTR (SNP) | VAF 17/46 reads (37%) | called by muse, mutect2, varscan2
- BTBD10 | c.1006+90G>A | Intron (SNP) | VAF 10/26 reads (38%) | called by mutect2, varscan2
- C19orf12 | c.*41C>T | 3'UTR (SNP) | VAF 14/101 reads (14%) | called by muse, mutect2, varscan2
- C8B | c.*187A>T | 3'UTR (SNP) | VAF 9/26 reads (35%) | called by muse, mutect2, varscan2
- CALHM5 | c.*2745C>G | 3'UTR (SNP) | VAF 30/70 reads (43%) | called by muse, mutect2, varscan2
- CDC14A | c.*186T>C | 3'UTR (SNP) | VAF 26/64 reads (41%) | called by muse, mutect2, varscan2
- CDK5 | c.194+47G>A | Intron (SNP) | VAF 80/197 reads (41%) | catalogued as rs750386255; called by muse, mutect2, varscan2
- CEP85L | c.*4454T>G | 3'UTR (SNP) | VAF 51/134 reads (38%) | called by muse, mutect2, varscan2
- CHST11 | c.*3003dup | 3'UTR (INS) | VAF 33/89 reads (37%) | catalogued as rs376255851; called by mutect2, varscan2
- CHST2 | c.*286T>A | 3'UTR (SNP) | VAF 46/110 reads (42%) | called by muse, mutect2, varscan2
- CLMP | c.*211C>A | 3'UTR (SNP) | VAF 59/85 reads (69%) | called by muse, mutect2, varscan2
- COL5A1 | c.109+10476C>A | Intron (SNP) | VAF 38/444 reads (9%) | called by muse, mutect2
- CPLANE1 | c.*1018T>A | 3'UTR (SNP) | VAF 29/111 reads (26%) | called by muse, mutect2, varscan2
- CPLX3 | c.*1349C>T | 3'UTR (SNP) | VAF 41/168 reads (24%) | catalogued as rs1426705692; called by muse, mutect2, varscan2
- DACH2 | c.1751-2538C>T | Intron (SNP) | VAF 13/16 reads (81%) | called by muse, mutect2, varscan2
- DDX11 | c.1369+102G>T | Intron (SNP) | VAF 18/45 reads (40%) | called by muse, varscan2
- DLAT | c.*754A>T | 3'UTR (SNP) | VAF 23/94 reads (24%) | called by muse, mutect2, varscan2
- DNAJB14 | c.*2546T>G | 3'UTR (SNP) | VAF 5/119 reads (4%) | called by muse, mutect2
- ENTHD1 | c.*489C>T | 3'UTR (SNP) | VAF 41/92 reads (45%) | called by muse, mutect2, varscan2
- ENTPD3 | c.1353+957G>T | Intron (SNP) | VAF 36/86 reads (42%) | catalogued as rs942112083; called by muse, mutect2, varscan2
- ETF1 | c.*1749A>G | 3'UTR (SNP) | VAF 28/110 reads (25%) | catalogued as rs1267127691; called by muse, mutect2, varscan2
- GLRA3 | c.*6610G>A | 3'UTR (SNP) | VAF 30/111 reads (27%) | called by muse, mutect2, varscan2
- GP2 | chr16:20309748 C>T | 3'Flank (SNP) | VAF 19/47 reads (40%) | called by muse, mutect2, varscan2
- GRAMD2B | c.654+41C>T | Intron (SNP) | VAF 41/195 reads (21%) | catalogued as rs200939023; called by muse, varscan2
- GRAMD2B | c.735+22C>G | Intron (SNP) | VAF 60/252 reads (24%) | catalogued as rs1409225635; called by muse, varscan2
- HNRNPA1 | c.*4+68G>A | Intron (SNP) | VAF 89/260 reads (34%) | called by muse, mutect2, varscan2
- HOXC11 | c.*2057G>A | 3'UTR (SNP) | VAF 22/52 reads (42%) | catalogued as rs1311395975; called by muse, mutect2, varscan2
- IGHV5-51 | c.-9T>G | 5'UTR (SNP) | VAF 37/116 reads (32%) | catalogued as rs1555541670; called by muse, mutect2, varscan2
- IGKV4-1 | c.-12A>C | 5'UTR (SNP) | VAF 9/41 reads (22%) | called by muse, varscan2
- LTB | c.163-145G>C | Intron (SNP) | VAF 82/204 reads (40%) | catalogued as rs140984421, COSV53000853; called by muse, mutect2, varscan2
- LTBR | c.194-9A>C | Intron (SNP) | VAF 20/55 reads (36%) | called by muse, mutect2, varscan2
- MAP3K20 | c.988-4087_988-4086insC | Intron (INS) | VAF 20/55 reads (36%) | catalogued as rs1216374687; called by mutect2, pindel, varscan2
- MERTK | c.*88C>A | 3'UTR (SNP) | VAF 75/231 reads (32%) | called by muse, varscan2
- MERTK | c.*150C>G | 3'UTR (SNP) | VAF 54/148 reads (36%) | called by muse, mutect2, varscan2
- MERTK | c.*266C>G | 3'UTR (SNP) | VAF 28/73 reads (38%) | catalogued as rs1422744793; called by muse, mutect2, varscan2
- MERTK | c.*408C>G | 3'UTR (SNP) | VAF 23/61 reads (38%) | catalogued as rs1029082445; called by muse, mutect2, varscan2
- MPZL1 | c.*83A>T | 3'UTR (SNP) | VAF 4/82 reads (5%) | called by muse, mutect2
- NFIB | c.*2059_*2060dup | 3'UTR (INS) | VAF 11/68 reads (16%) | catalogued as rs982064840; called by mutect2, varscan2
- NOP56 | c.909+76C>T | Intron (SNP) | VAF 6/35 reads (17%) | catalogued as rs1266091735; called by muse, mutect2, varscan2
- PPIP5K2 | c.*687A>G | 3'UTR (SNP) | VAF 13/43 reads (30%) | called by muse, mutect2, varscan2
- RAB27B | c.*2492A>T | 3'UTR (SNP) | VAF 18/64 reads (28%) | called by muse, mutect2, varscan2
- SEMA3A | c.*1182G>A | 3'UTR (SNP) | VAF 23/64 reads (36%) | called by muse, mutect2, varscan2
- SERPINA1 | c.*812G>A | 3'UTR (SNP) | VAF 4/95 reads (4%) | called by muse, mutect2
- SLC2A2 | c.*943A>G | 3'UTR (SNP) | VAF 42/111 reads (38%) | called by muse, mutect2, varscan2
- SNX22 | c.460+98C>T | Intron (SNP) | VAF 32/136 reads (24%) | catalogued as rs1227355794; called by muse, mutect2, varscan2
- STX4 | c.-22G>A | 5'UTR (SNP) | VAF 38/114 reads (33%) | catalogued as rs1306473134; called by muse, mutect2, varscan2
- SYN3 | c.-88C>T | 5'UTR (SNP) | VAF 5/79 reads (6%) | called by muse, mutect2
- TMEM132B | c.*1875C>T | 3'UTR (SNP) | VAF 34/95 reads (36%) | called by muse, mutect2, varscan2
- TMTC2 | c.*2121A>C | 3'UTR (SNP) | VAF 20/64 reads (31%) | called by muse, mutect2, varscan2
- TNPO2 | c.1669-50_1669-49del | Intron (DEL) | VAF 20/98 reads (20%) | catalogued as rs1197233836; called by pindel, varscan2
- TRAK1 | c.*817G>A | 3'UTR (SNP) | VAF 40/110 reads (36%) | called by muse, mutect2, varscan2
- TUT7 | c.1609-940C>T | Intron (SNP) | VAF 41/171 reads (24%) | called by muse, mutect2, varscan2
- UBE2H | c.*3362_*3379del | 3'UTR (DEL) | VAF 14/66 reads (21%) | called by mutect2, pindel, varscan2
- USH2A | c.4627+128A>C | Intron (SNP) | VAF 37/104 reads (36%) | called by muse, mutect2, varscan2
- VAMP4 | c.*135A>G | 3'UTR (SNP) | VAF 49/115 reads (43%) | catalogued as rs886325583; called by muse, mutect2, varscan2
- ZRANB3 | c.*3227G>C | 3'UTR (SNP) | VAF 13/47 reads (28%) | called by muse, mutect2, varscan2
- ZRANB3 | c.*2785G>A | 3'UTR (SNP) | VAF 28/64 reads (44%) | called by muse, varscan2
- ZRANB3 | c.*2585G>T | 3'UTR (SNP) | VAF 85/210 reads (40%) | called by muse, mutect2, varscan2
- ZRANB3 | c.*1565G>C | 3'UTR (SNP) | VAF 31/87 reads (36%) | called by muse, mutect2, varscan2
- ZRANB3 | c.*1391G>A | 3'UTR (SNP) | VAF 34/103 reads (33%) | called by muse, mutect2, varscan2
